Somatic mutation profile of tumor specimen HCM-BROD-0485-C15-06A (aliquot HCM-BROD-0485-C15-06A-01D-A83U-36) from HCMI case HCM-BROD-0485-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 46.5 years (16,967 days).
Specimen HCM-BROD-0485-C15-06A: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 125dcbc8-005a-4d98-bc9f-1fb78e8fa6aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0485-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0485-C15-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72009803-1b9d-42ff-92a2-b70bc582bc50

The open-access MAF lists 167 somatic variants for this specimen: 124 protein-altering or splice-affecting, 36 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 112, Silent 36, Nonsense Mutation 4, Intron 3, Frame Shift Del 2, RNA 2, Splice Region 2, Nonstop Mutation 1, Frame Shift Ins 1, Translation Start Site 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC4A11 | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 134/211 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121909388, CM063151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPTA1 | c.5195A>C p.K1732T | Missense Mutation (SNP) | VAF 112/288 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370558180, COSV100934623, COSV100935599; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 190/285 reads (67%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AFDN | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 93/150 reads (62%) | catalogued as COSV60041076; called by muse, mutect2, varscan2
- APOB | c.2683G>A p.A895T | Missense Mutation (SNP) | VAF 177/779 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.859); catalogued as rs371884333, COSV99265146; called by muse, mutect2, varscan2
- ARNT2 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 150/355 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs765287094; called by muse, mutect2, varscan2
- ATG2B | c.5368G>A p.E1790K | Missense Mutation (SNP) | VAF 126/349 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as COSV55890618; called by muse, mutect2, varscan2
- AURKB | c.550T>G p.L184V | Missense Mutation (SNP) | VAF 92/150 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as rs747492163; called by muse, mutect2, varscan2
- AZIN2 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 212/463 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs374895105; called by muse, mutect2, varscan2
- CALD1 | c.14A>G p.E5G | Missense Mutation (SNP) | VAF 74/390 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV62645511; called by muse, mutect2, varscan2
- CATSPER2 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 137/363 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376517321, COSV58660267; called by muse, mutect2, varscan2
- CDH6 | c.2275G>A p.D759N | Missense Mutation (SNP) | VAF 29/572 reads (5%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.952); catalogued as COSV54063505; called by muse, mutect2
- CDRT15L2 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 126/291 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.833); catalogued as rs771538435; called by muse, mutect2, varscan2
- CFAP46 | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 178/419 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs532867979; called by muse, mutect2, varscan2
- CILP2 | c.2122C>T p.R708C | Missense Mutation (SNP) | VAF 224/681 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1472767769, COSV52273486; called by muse, mutect2, varscan2
- CIPC | c.382T>G p.L128V | Missense Mutation (SNP) | VAF 138/420 reads (33%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV62377248; called by muse, mutect2, varscan2
- CSH2 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 164/830 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs755600756, COSV100400231; called by muse, mutect2, varscan2
- CYFIP1 | c.1856C>T p.S619L | Missense Mutation (SNP) | VAF 147/460 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs756767407; called by muse, mutect2, varscan2
- DENND6A | c.1353A>T p.L451F | Missense Mutation (SNP) | VAF 73/267 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1338285827; called by muse, mutect2
- EBF2 | c.1268G>A p.G423D | Missense Mutation (SNP) | VAF 327/608 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV101282264; called by muse, mutect2, varscan2
- FAM187B | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1389739363; called by muse, mutect2, varscan2
- FAM234A | c.1015G>A p.G339S | Missense Mutation (SNP) | VAF 191/526 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.23); catalogued as rs774996392, COSV51452809; called by muse, mutect2, varscan2
- FAM240B | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.773); catalogued as rs975294952; called by muse, mutect2
- FAT4 | c.8657T>G p.L2886R | Missense Mutation (SNP) | VAF 99/237 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58674921, COSV58711887; called by muse, mutect2, varscan2
- HAT1 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 74/322 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs368462108; called by muse, mutect2, varscan2
- HCN4 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 71/221 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758468167, COSV56084416, COSV99984381; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ICE1 | c.3645A>G p.I1215M | Missense Mutation (SNP) | VAF 71/298 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.234); catalogued as rs762694872; called by muse, mutect2, varscan2
- KCTD4 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 88/142 reads (62%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.277); catalogued as rs562563207, COSV61242345; called by muse, mutect2, varscan2
- KHDRBS3 | c.7_9del p.E3? | Translation Start Site (DEL) | VAF 132/712 reads (19%) | catalogued as rs775225910; called by pindel, varscan2
- KLHL40 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 82/660 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as rs1310855261; called by muse, mutect2, varscan2
- MRNIP | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 258/574 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs562422912, COSV52975381; called by muse, mutect2
- MYF6 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 120/305 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57351550; called by muse, mutect2, varscan2
- OR4C15 | c.188A>G p.E63G (on ENST00000314644; = p.E9G on NM_001001920.2) | Missense Mutation (SNP) | VAF 88/271 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as COSV58951804, COSV58951861; called by muse, mutect2, varscan2
- PCDH19 | c.2508G>C p.E836D (on ENST00000373034 / NM_001184880.2; = p.E789D on NM_020766.3) | Missense Mutation (SNP) | VAF 234/276 reads (85%) | SIFT tolerated (0.48); PolyPhen benign (0.385); catalogued as COSV55263636; called by muse, mutect2, varscan2
- PDLIM1 | c.695A>G p.N232S | Missense Mutation (SNP) | VAF 76/302 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs1201013714; called by muse, mutect2, varscan2
- PDXP | c.362_373del p.E121_A124del | In Frame Del (DEL) | VAF 124/404 reads (31%) | catalogued as rs897458816; called by mutect2, varscan2
- PKD1 | c.2512G>A p.V838M | Missense Mutation (SNP) | VAF 262/619 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.406); catalogued as rs764575507; called by muse, mutect2, varscan2
- PROS1 | c.122G>C p.R41P | Missense Mutation (SNP) | VAF 188/366 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM163572, CM951040, COSV62399187; called by muse, mutect2, varscan2
- RYR1 | c.2180G>A p.R727H | Missense Mutation (SNP) | VAF 29/237 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs372460800; called by muse, mutect2, varscan2
- SEC24B | c.3146C>T p.S1049L | Missense Mutation (SNP) | VAF 105/367 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.046); catalogued as rs199826133, COSV99493536; called by muse, mutect2, varscan2
- SHANK1 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 249/638 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs954426144; called by muse, mutect2, varscan2
- SLC22A7 | c.1066G>A p.G356R (on ENST00000372585 / NM_153320.2; = p.G354R on NM_006672.3) | Missense Mutation (SNP) | VAF 124/172 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1205738663; called by muse, mutect2, varscan2
- SLC39A10 | c.1353G>T p.M451I | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as COSV100660638; called by muse, mutect2
- SMARCA4 | c.4805A>C p.K1602T | Missense Mutation (SNP) | VAF 176/296 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.722); catalogued as rs1485676007; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPTAN1 | c.6767G>A p.R2256Q | Missense Mutation (SNP) | VAF 22/492 reads (4%) | SIFT tolerated (0.68); PolyPhen benign (0.049); catalogued as COSV63985273; called by muse, mutect2
- SSH3 | c.734A>G p.E245G | Missense Mutation (SNP) | VAF 198/542 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1371698874; called by muse, mutect2, varscan2
- TBC1D2 | c.2656C>T p.R886W (on ENST00000465784 / NM_001267571.2; = p.R875W on NM_018421.4) | Missense Mutation (SNP) | VAF 180/471 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as rs753913278, COSV59784403, COSV59789580; called by muse, varscan2
- TEX13C | c.2534A>G p.K845R | Missense Mutation (SNP) | VAF 192/241 reads (80%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as COSV101084795; called by muse, mutect2, varscan2
- TLN2 | c.6143C>T p.A2048V | Missense Mutation (SNP) | VAF 40/680 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs137970385, COSV60890419; called by muse, mutect2
- TM9SF2 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs372811557; called by muse, mutect2, varscan2
- WIZ | c.5131C>T p.R1711C (on ENST00000673675 / NM_001371589.1; = p.R616C on NM_021241.3) | Missense Mutation (SNP) | VAF 231/1491 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1312221467, COSV99652657; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1311A>C p.K437N | Missense Mutation (SNP) | VAF 118/416 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56271980; called by muse, mutect2, varscan2
- ZNF385C | c.670A>G p.S224G | Missense Mutation (SNP) | VAF 94/250 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1460258675; called by muse, mutect2, varscan2
- ZNF568 | c.1749A>C p.K583N | Missense Mutation (SNP) | VAF 92/188 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV101426849, COSV71278656, COSV71279101; called by muse, mutect2, varscan2
- ZNF717 | c.297C>A p.D99E | Missense Mutation (SNP) | VAF 45/351 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.506); catalogued as rs1420738328; called by muse, mutect2
- ASXL3 | c.4319A>C p.N1440T | Missense Mutation (SNP) | VAF 289/559 reads (52%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- BAHD1 | c.365T>C p.L122P | Missense Mutation (SNP) | VAF 164/511 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- BTBD8 | c.5179T>C p.Y1727H (on ENST00000636805 / NM_001376131.1; = p.Y1214H on NM_015237.4) | Missense Mutation (SNP) | VAF 69/208 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C2CD4D | c.247_248del p.P83Sfs*273 | Frame Shift Del (DEL) | VAF 191/751 reads (25%) | called by mutect2, pindel, varscan2
- CARM1 | c.668A>C p.E223A | Missense Mutation (SNP) | VAF 109/173 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- CCDC141 | c.3505A>T p.I1169F | Missense Mutation (SNP) | VAF 107/478 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- CDH10 | c.677A>G p.N226S | Missense Mutation (SNP) | VAF 110/377 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CENPE | c.790_791insG p.I264Sfs*10 | Frame Shift Ins (INS) | VAF 93/242 reads (38%) | called by mutect2, pindel, varscan2
- CFH | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CPNE2 | c.493A>G p.R165G | Missense Mutation (SNP) | VAF 112/365 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, varscan2
- DENND6A | c.1408A>G p.S470G | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- DSEL | c.1826G>A p.S609N | Missense Mutation (SNP) | VAF 114/285 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DYNC2I1 | c.3038A>G p.K1013R | Missense Mutation (SNP) | VAF 45/1062 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.03); called by muse, mutect2
- EXOC6B | c.183C>G p.D61E | Missense Mutation (SNP) | VAF 119/432 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- FGF17 | c.500A>G p.Q167R | Missense Mutation (SNP) | VAF 253/973 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- FSCN1 | c.919T>C p.F307L | Missense Mutation (SNP) | VAF 214/836 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FSHR | c.1114A>T p.I372F | Missense Mutation (SNP) | VAF 125/576 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- GCN1 | c.6949A>G p.R2317G | Missense Mutation (SNP) | VAF 143/451 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM6 | c.938C>A p.T313N | Missense Mutation (SNP) | VAF 196/508 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRM6 | c.731G>A p.C244Y | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- HSF1 | c.176A>G p.K59R | Missense Mutation (SNP) | VAF 166/1081 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- ICE1 | c.3644T>A p.I1215K | Missense Mutation (SNP) | VAF 68/293 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- IL17D | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 306/662 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- INO80 | c.4063A>T p.S1355C | Missense Mutation (SNP) | VAF 111/303 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- IRF3 | c.625T>G p.F209V | Missense Mutation (SNP) | VAF 262/612 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ISL1 | c.380T>C p.L127P | Missense Mutation (SNP) | VAF 37/553 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.333); called by muse, mutect2
- ITGA11 | c.2654A>T p.E885V | Missense Mutation (SNP) | VAF 119/330 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.315); called by mutect2, varscan2
- KCNF1 | c.922T>G p.S308A | Missense Mutation (SNP) | VAF 225/970 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- KLHL38 | c.425T>C p.L142P | Missense Mutation (SNP) | VAF 124/946 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KMT2C | c.10795G>T p.E3599* | Nonsense Mutation (SNP) | VAF 229/429 reads (53%) | called by muse, mutect2, varscan2
- LOXHD1 | c.3150G>C p.E1050D | Missense Mutation (SNP) | VAF 285/609 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- LRRC4B | c.541G>A p.V181M | Missense Mutation (SNP) | VAF 219/556 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MARS1 | c.227A>G p.E76G | Missense Mutation (SNP) | VAF 78/463 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAST4 | c.3541A>C p.S1181R (on ENST00000403625 / NM_001164664.2; = p.S992R on NM_015183.3) | Missense Mutation (SNP) | VAF 116/307 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MATN1 | c.88T>A p.S30T | Missense Mutation (SNP) | VAF 128/390 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.005); called by mutect2, varscan2
- MMRN2 | c.2126A>C p.K709T | Missense Mutation (SNP) | VAF 203/642 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MPPED1 | c.747G>T p.L249= | Splice Region (SNP) | VAF 196/255 reads (77%) | called by muse, mutect2, varscan2
- MYO3B | c.1771A>T p.I591F | Missense Mutation (SNP) | VAF 69/302 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- NAV2 | c.6229C>G p.L2077V (on ENST00000396087 / NM_001244963.2; = p.L2018V on NM_145117.5) | Missense Mutation (SNP) | VAF 157/403 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NRG3 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 61/201 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NSF | c.1442T>C p.L481P | Missense Mutation (SNP) | VAF 69/220 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR52D1 | c.758T>G p.V253G | Missense Mutation (SNP) | VAF 32/592 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2
- OTUD3 | c.1197A>G p.*399Wext*19 | Nonstop Mutation (SNP) | VAF 123/342 reads (36%) | called by muse, mutect2, varscan2
- PCDHGB3 | c.344A>G p.N115S | Missense Mutation (SNP) | VAF 153/435 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- PDPK1 | c.1543T>G p.F515V | Missense Mutation (SNP) | VAF 134/355 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- PI15 | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 108/690 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHG5 | c.2311T>A p.S771T (on ENST00000400915 / NM_001042663.3; = p.S734T on NM_020631.6) | Missense Mutation (SNP) | VAF 190/773 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, varscan2
- PRR19 | c.208A>G p.S70G | Missense Mutation (SNP) | VAF 173/335 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RASA2 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 76/300 reads (25%) | called by muse, mutect2, varscan2
- RFX1 | c.610T>A p.S204T | Missense Mutation (SNP) | VAF 106/194 reads (55%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ROBO3 | c.1916A>C p.E639A | Missense Mutation (SNP) | VAF 132/418 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- SH3TC2 | c.535T>G p.F179V | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- SLC9B1 | c.112A>G p.T38A | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- SLITRK3 | c.1709T>C p.L570P | Missense Mutation (SNP) | VAF 17/549 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2
- SNCG | c.298T>A p.L100M | Missense Mutation (SNP) | VAF 65/250 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- SPA17 | c.242A>T p.E81V | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- STING1 | c.967T>G p.F323V | Missense Mutation (SNP) | VAF 96/505 reads (19%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- STOX1 | c.2381T>C p.L794P | Missense Mutation (SNP) | VAF 156/468 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SZT2 | c.7447_7448del p.S2483Cfs*8 (on ENST00000634258 / NM_001365999.1; = p.S2426Cfs*8 on NM_015284.4) | Frame Shift Del (DEL) | VAF 294/772 reads (38%) | called by pindel, varscan2
- TAF1L | c.1714C>T p.Q572* | Nonsense Mutation (SNP) | VAF 16/377 reads (4%) | called by muse, mutect2
- TBL1XR1 | c.1114A>C p.T372P | Missense Mutation (SNP) | VAF 57/529 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- TJP2 | c.621A>C p.Q207H | Missense Mutation (SNP) | VAF 252/815 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0); called by mutect2, varscan2
- TNIK | c.3421T>A p.L1141M | Missense Mutation (SNP) | VAF 60/571 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- TRIM49 | c.419T>G p.L140R | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- VAMP7 | c.62G>T p.C21F | Missense Mutation (SNP) | VAF 164/520 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- YTHDF2 | c.1045A>C p.T349P | Missense Mutation (SNP) | VAF 132/507 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZDHHC22 | c.528A>T p.G176= | Splice Region (SNP) | VAF 81/257 reads (32%) | called by muse, mutect2, varscan2
- ZFHX4 | c.7532A>T p.H2511L | Missense Mutation (SNP) | VAF 360/906 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF613 | c.461C>T p.S154F (on ENST00000293471 / NM_001031721.4; = p.S118F on NM_024840.4) | Missense Mutation (SNP) | VAF 82/115 reads (71%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADCK5 | c.1077G>A p.S359= | Silent (SNP) | VAF 157/903 reads (17%) | catalogued as rs782110176, COSV58233831; called by muse, mutect2, varscan2
- ASH1L | c.2523G>T p.G841= | Silent (SNP) | VAF 84/279 reads (30%) | called by muse, mutect2, varscan2
- B4GALNT1 | c.672T>C p.T224= | Silent (SNP) | VAF 185/836 reads (22%) | called by muse, mutect2, varscan2
- BCR | c.2979C>T p.S993= | Silent (SNP) | VAF 129/528 reads (24%) | called by muse, mutect2, varscan2
- CCDC24 | c.918A>G p.P306= | Silent (SNP) | VAF 124/495 reads (25%) | called by muse, mutect2, varscan2
- CDH6 | c.2274G>A p.T758= | Silent (SNP) | VAF 29/574 reads (5%) | called by muse, mutect2
- COL11A1 | c.4038T>C p.P1346= | Silent (SNP) | VAF 111/268 reads (41%) | called by muse, mutect2, varscan2
- CTNNAL1 | c.1857T>C p.T619= | Silent (SNP) | VAF 44/151 reads (29%) | called by muse, mutect2, varscan2
- DENND4B | c.414C>T p.P138= | Silent (SNP) | VAF 147/588 reads (25%) | catalogued as rs752945372; called by muse, mutect2, varscan2
- FCRL3 | c.1212T>C p.C404= | Silent (SNP) | VAF 127/307 reads (41%) | called by muse, mutect2, varscan2
- FZR1 | c.21G>C p.R7= | Silent (SNP) | VAF 181/245 reads (74%) | called by muse, mutect2, varscan2
- GRIN3B | c.675A>G p.P225= | Silent (SNP) | VAF 259/699 reads (37%) | catalogued as rs1336913851; called by muse, mutect2, varscan2
- KCNT2 | c.981C>T p.L327= | Silent (SNP) | VAF 42/137 reads (31%) | catalogued as rs756536646; called by muse, mutect2, varscan2
- KIF7 | c.2586C>T p.R862= | Silent (SNP) | VAF 169/446 reads (38%) | catalogued as rs141097070; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- KLHL14 | c.1038C>T p.D346= | Silent (SNP) | VAF 121/554 reads (22%) | catalogued as rs780531893, COSV63830298; called by muse, mutect2, varscan2
- LRRC6 | c.250T>C p.L84= | Silent (SNP) | VAF 54/319 reads (17%) | catalogued as rs750250466; called by muse, mutect2, varscan2
- LYAR | c.774C>T p.S258= | Silent (SNP) | VAF 195/512 reads (38%) | catalogued as rs781568883; called by muse, mutect2, varscan2
- MOB2 | c.157C>T p.L53= | Silent (SNP) | VAF 35/643 reads (5%) | catalogued as rs1266745885; called by muse, mutect2
- MRPS15 | c.135C>T p.L45= | Silent (SNP) | VAF 152/505 reads (30%) | catalogued as rs748086571; called by muse, mutect2, varscan2
- NEDD4L | c.2721A>C p.R907= (on ENST00000400345 / NM_001144967.3; = p.R887= on NM_015277.6) | Silent (SNP) | VAF 499/719 reads (69%) | called by muse, mutect2, varscan2
- NET1 | c.1239T>C p.T413= (on ENST00000355029 / NM_001047160.3; = p.T359= on NM_005863.5) | Silent (SNP) | VAF 118/210 reads (56%) | called by muse, varscan2
- NYNRIN | c.3276C>T p.T1092= | Silent (SNP) | VAF 204/559 reads (36%) | catalogued as rs371702363; called by muse, mutect2, varscan2
- PGBD5 | c.90C>T p.D30= | Silent (SNP) | VAF 153/517 reads (30%) | catalogued as rs1269287672; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.1161T>C p.T387= (on ENST00000421990 / NM_001136042.2; = p.T369= on NM_025267.3) | Silent (SNP) | VAF 79/360 reads (22%) | called by muse, mutect2, varscan2
- RAB11FIP3 | c.624A>C p.R208= | Silent (SNP) | VAF 216/683 reads (32%) | called by muse, mutect2, varscan2
- RANBP10 | c.588C>T p.L196= | Silent (SNP) | VAF 117/293 reads (40%) | catalogued as rs1212480444; called by muse, mutect2, varscan2
- SAMD9L | c.1782A>G p.L594= | Silent (SNP) | VAF 85/326 reads (26%) | called by muse, mutect2, varscan2
- SCN10A | c.4917C>T p.D1639= | Silent (SNP) | VAF 182/429 reads (42%) | catalogued as rs142804903; called by muse, mutect2, varscan2
- SHROOM2 | c.4632C>T p.D1544= | Silent (SNP) | VAF 205/241 reads (85%) | catalogued as rs200352588, COSV66606921; called by muse, mutect2, varscan2
- SLC4A4 | c.2538C>A p.V846= (on ENST00000264485 / NM_001098484.3; = p.V802= on NM_003759.4) | Silent (SNP) | VAF 116/378 reads (31%) | called by muse, varscan2
- SLC52A2 | c.75T>C p.A25= | Silent (SNP) | VAF 344/1076 reads (32%) | called by muse, mutect2, varscan2
- SPTA1 | c.3273A>T p.A1091= | Silent (SNP) | VAF 13/440 reads (3%) | called by muse, mutect2
- TBC1D17 | c.486C>T p.R162= | Silent (SNP) | VAF 283/633 reads (45%) | catalogued as rs1444774989; called by muse, mutect2, varscan2
- TGFBRAP1 | c.186G>A p.T62= | Silent (SNP) | VAF 163/665 reads (25%) | called by muse, mutect2, varscan2
- TRAF1 | c.1248T>A p.T416= | Silent (SNP) | VAF 80/227 reads (35%) | called by muse, mutect2, varscan2
- TTN | c.2034T>A p.T678= (on ENST00000591111; = p.T632= on NM_003319.4) | Silent (SNP) | VAF 57/261 reads (22%) | called by muse, mutect2, varscan2
- ARHGEF1 | c.*258A>C | 3'UTR (SNP) | VAF 177/523 reads (34%) | called by muse, mutect2, varscan2
- DIRC1 | n.368C>T | RNA (SNP) | VAF 372/659 reads (56%) | catalogued as rs538669584; called by muse, mutect2, varscan2
- EPB41L3 | c.2350-1237A>G | Intron (SNP) | VAF 77/244 reads (32%) | called by muse, mutect2, varscan2
- INSRR | c.3397+29G>A | Intron (SNP) | VAF 147/335 reads (44%) | catalogued as rs777227609, COSV63870785; called by muse, mutect2, varscan2
- LMO7DN | n.116G>A | RNA (SNP) | VAF 86/306 reads (28%) | called by muse, varscan2
- SYCE1 | chr10:133554289 T>A | 3'Flank (SNP) | VAF 90/310 reads (29%) | called by muse, mutect2, varscan2
- UMOD | c.89-601G>A | Intron (SNP) | VAF 108/335 reads (32%) | catalogued as rs776436785; called by muse, mutect2, varscan2
